Somatic mutation profile of tumor specimen TCGA-CV-5976-01A (aliquot TCGA-CV-5976-01A-11D-1683-08) from TCGA case TCGA-CV-5976, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 50.0 years (18,267 days).
Specimen TCGA-CV-5976-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57c4d742-cd07-46f6-bb9d-f02d0d60f5db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-5976-11A (Solid Tissue Normal), aliquot TCGA-CV-5976-11A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05466239-fb7a-4892-8894-cef7cee47d89

The open-access MAF lists 78 somatic variants for this specimen: 58 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 48, Silent 20, Nonsense Mutation 6, Frame Shift Del 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11552822, CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 50/188 reads (27%) | catalogued as rs746497630; called by mutect2, varscan2
- ADAM29 | c.679G>T p.V227F | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0.118); catalogued as COSV63661319, COSV63661707; called by muse, mutect2, varscan2
- ADGRL3 | c.1097A>T p.E366V (on ENST00000506720 / NM_001322402.2; = p.E298V on NM_015236.6) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72267048; called by muse, mutect2, varscan2
- AGMO | c.155T>A p.L52Q | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV61108313; called by muse, mutect2, varscan2
- ARF4 | c.181A>G p.I61V | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.034); catalogued as COSV57714681; called by muse, mutect2, varscan2
- ARID2 | c.2710C>T p.Q904* | Nonsense Mutation (SNP) | VAF 15/81 reads (19%) | catalogued as COSV57597329; called by muse, mutect2, varscan2
- BRINP2 | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763172017, COSV64175944; called by muse, mutect2, varscan2
- CDS1 | c.1255A>T p.R419W | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV55687135; called by muse, mutect2, varscan2
- CR1 | c.2611del p.C871Vfs*26 | Frame Shift Del (DEL) | VAF 12/75 reads (16%) | catalogued as rs1558236830; called by pindel, varscan2*
- DCC | c.3148A>C p.M1050L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as COSV59087857; called by muse, mutect2, varscan2
- DHX34 | c.137A>G p.E46G | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV60894709; called by muse, mutect2, varscan2
- DOK6 | c.712A>T p.M238L | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66926998; called by muse, mutect2, varscan2
- ELMO1 | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as COSV60297090; called by muse, mutect2, varscan2
- EPDR1 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52258571; called by muse, mutect2, varscan2
- ETV1 | c.1415A>G p.N472S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1175100756, COSV54138878; called by muse, mutect2, varscan2
- FAT1 | c.12440G>A p.G4147D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV71672858; called by muse, mutect2, varscan2
- FCRLB | c.904C>A p.P302T | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as COSV100396328, COSV61059790; called by muse, mutect2
- FCRLB | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100396330; called by muse, mutect2, varscan2
- FN1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV60548534; called by muse, mutect2, varscan2
- FPGT | c.1715A>G p.Y572C | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs372383046, COSV63836227; called by muse, mutect2, varscan2
- GLYAT | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53538738, COSV53540040; called by muse, mutect2, varscan2
- H4C12 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV100694731, COSV100694760, COSV100694763; called by muse, mutect2, varscan2
- HLA-A | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as COSV65136444, COSV65138215; called by muse, mutect2, varscan2
- HMGCR | c.2297A>G p.Q766R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55314886; called by muse, mutect2, varscan2
- HRNR | c.1405G>C p.E469Q | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.265); catalogued as COSV64255569; called by muse, mutect2, varscan2
- HRNR | c.1284G>C p.Q428H | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV64255574; called by muse, mutect2, varscan2
- LRP1B | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs776305678, COSV67188037; called by muse, mutect2, varscan2
- MAP3K6 | c.3647C>G p.S1216* | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | catalogued as COSV58870808; called by muse, mutect2, varscan2
- MAP6 | c.1930C>T p.P644S | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as COSV59074782; called by muse, mutect2, varscan2
- MAPKBP1 | c.2020A>T p.I674F (on ENST00000456763 / NM_001128608.2; = p.I668F on NM_014994.3) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as COSV52958640; called by muse, mutect2, varscan2
- NELL2 | c.736G>C p.D246H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.91); catalogued as COSV61570142; called by muse, mutect2, varscan2
- PAN2 | c.1007T>A p.F336Y | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV57753148; called by muse, mutect2, varscan2
- PCNX3 | c.3211G>A p.V1071I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1294105116, COSV63135544; called by muse, mutect2, varscan2
- PDIK1L | c.902A>G p.N301S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV65322421; called by muse, mutect2, varscan2
- PIK3CG | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV100783008; called by muse, mutect2, varscan2
- PLEC | c.10538G>A p.R3513H (on ENST00000322810 / NM_201380.4; = p.R3403H on NM_000445.5) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.616); catalogued as rs781908703, COSV100517719; called by muse, mutect2, varscan2
- PPP1R12C | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54736196; called by muse, varscan2
- PRDM11 | c.1460C>T p.S487L (on ENST00000530656 / NM_001359633.1; = p.S453L on NM_001256695.1) | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as rs750876126, COSV55438049; called by muse, mutect2, varscan2
- RAB1B | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV61012217, COSV61012363; called by muse, mutect2
- RB1CC1 | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs151174558; called by muse, mutect2, varscan2
- RSPH9 | c.678G>T p.W226C | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64521860; called by muse, mutect2, varscan2
- SART1 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as rs538739713, COSV100409072; called by muse, mutect2
- SMOC1 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs899963298, COSV62759762; called by muse, mutect2, varscan2
- STAB1 | c.5096G>A p.G1699D | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58732891; called by muse, mutect2, varscan2
- TMEM132D | c.2193C>A p.F731L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV67158945; called by muse, mutect2, varscan2
- TMEM132D | c.937A>G p.R313G | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as COSV70595724, COSV70619850; called by muse, mutect2, varscan2
- TRMT13 | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV54926993; called by muse, mutect2, varscan2
- UBE4A | c.731A>C p.D244A (on ENST00000252108 / NM_001204077.2; = p.D251A on NM_004788.4) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs111254610; called by muse, mutect2, varscan2
- ZFP36 | c.431G>A p.R144H (on ENST00000594442; = p.R138H on NM_003407.5) | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50527602; called by muse, mutect2, varscan2
- ZNF26 | c.857A>G p.Y286C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV60806603; called by muse, mutect2, varscan2
- ZNF510 | c.962C>G p.S321* | Nonsense Mutation (SNP) | VAF 31/103 reads (30%) | catalogued as COSV56296617; called by muse, mutect2, varscan2
- ZNF721 | c.1592T>A p.I531N (on ENST00000338977; = p.I543N on NM_133474.4) | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.948); catalogued as rs200851544, COSV59089315; called by muse, mutect2, varscan2
- GPR179 | c.4058G>T p.S1353I (on ENST00000621958; = p.S1352I on NM_001004334.4) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- MGA | c.2836_2838del p.I946del | In Frame Del (DEL) | VAF 36/122 reads (30%) | called by pindel, varscan2
- POLR3C | c.584dup p.L195Ffs*6 | Frame Shift Ins (INS) | VAF 21/79 reads (27%) | called by mutect2, pindel, varscan2
- ADAM11 | c.2244C>T p.A748= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV52345000; called by muse, mutect2, varscan2
- B3GLCT | c.1173G>A p.T391= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs369715616; called by muse, mutect2, varscan2
- CACNA1E | c.2616C>T p.T872= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV62385733; called by muse, mutect2, varscan2
- CDYL | c.1089G>A p.E363= (on ENST00000328908 / NM_001368125.1; = p.E309= on NM_004824.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as rs774469826, COSV59358778; called by muse, mutect2, varscan2
- DMAC2L | c.588A>G p.K196= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV55413008; called by muse, mutect2, varscan2
- EPHA10 | c.321C>T p.F107= | Silent (SNP) | VAF 46/160 reads (29%) | catalogued as COSV60402572, COSV60404007; called by muse, mutect2, varscan2
- EPPK1 | c.2889G>A p.L963= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV101599929; called by muse, mutect2
- FKBP8 | c.711C>T p.F237= (on ENST00000222308 / NM_001308373.2; = p.F238= on NM_012181.5) | Silent (SNP) | VAF 6/99 reads (6%) | catalogued as rs1027995315, COSV55893650; called by muse, mutect2
- FLYWCH1 | c.1290C>T p.F430= (on ENST00000253928 / NM_001308068.2; = p.F429= on NM_020912.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1160895901, COSV54144347; called by muse, mutect2, varscan2
- GABRA4 | c.1476C>T p.T492= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV99974503; called by muse, mutect2, varscan2
- GCM2 | c.942C>T p.V314= | Silent (SNP) | VAF 54/190 reads (28%) | catalogued as COSV65275249; called by muse, mutect2, varscan2
- HSPA1L | c.1266C>T p.I422= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as rs750528670, COSV65148775; called by muse, mutect2, varscan2
- KCNB1 | c.879C>T p.R293= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV65566814; called by muse, mutect2, varscan2
- LCT | c.5655C>T p.Y1885= | Silent (SNP) | VAF 34/190 reads (18%) | catalogued as rs1483785677, COSV51545802; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LONP1 | c.1608C>T p.I536= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as rs376139384; called by muse, mutect2, varscan2
- MOV10 | c.2328C>T p.I776= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV53516923; called by muse, mutect2, varscan2
- PRDM2 | c.2634A>G p.V878= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as COSV52444119; called by muse, mutect2, varscan2
- SIX2 | c.861G>A p.V287= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs1421332463, COSV57390424, COSV57391110; called by muse, mutect2, varscan2
- SYPL2 | c.714G>C p.P238= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV100881477; called by muse, mutect2, varscan2
- TIGD3 | c.372G>A p.L124= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV99361864; called by muse, mutect2, varscan2
